Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5K4, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5K4-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: F
ADM DATE:

PAT TYPE:

OPER DATE:

PROCEDURE: SPHS

Right adrenal mass. Two short stitches adrenal vein with thrombus coming out of vein. Two long inferior aspect of tumor. One long lateral aspect of tumor. Two double long superior aspect of tumor. Inking according to sarcoma template. Yellow anterior, blue superior, green inferior, red medial, orange lateral, black posterior.

PROCEDURE: SPGD

1. "Adrenal gland." Received in formalin in a large container is a 1060 gm (15.5 x 14.5 x 13.5 cm) adrenal gland with attached partially disrupted vessel oriented as above. The gland is surrounded by a thin membranous capsule and an 8.0 x 6.0 x 1.3 cm segment of fibroadipose tissue is attached to the inferior surface. The vessel extending from the medial surface is partially disrupted exposing a tumor mass in the vascular lumen. Per the surgeon, this does not represent a real margin as the tumor mass extended upwards towards the atrium. Inking as follows: Yellow anterior, blue superior, green inferior, red medial, orange lateral, black posterior. Sectioning reveals a tan parenchyma that is focally hemorrhagic and largely necrotic extending the entire dimension of the gland. A central area of yellow discoloration is noted, 3.5 x 1.0 cm, near the center of the specimen. No lymph nodes are present within the attached fibroadipose tissue.

1A-B. Representative sections of tumor to inferior margin.

1C-D. Representative sections of tumor to anterior margin.

1E-F. Representative sections of tumor to superior margin.

1G-H. Representative section of tumor to medial margin.

1I-J. Representative sections of tumor to posterior margin.

1K-L. Representative section of tumor to lateral margin.

1M-N. Representative section of tumor in areas of yellow discoloration.

10. Representative sections of tumor within attached vessel.
Photographs taken.

ICD-O-3

PROCEDURE: SPMI

ADRENOCORTICAL CARCINOMA

Tumor Size: 15.5 x 14.5 x 13.5 cm.

Tumor Weight: 1060 grams.

Capsular Invasion: No.

Carcinoma, adrenal cortex
8370/3
Site: Adrenal Gland, cortex
C74.2

J2/30/13

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: F
ADM DATE:

BIRTHDATE:

PAT TYPE:

OPER DATE:

Vascular Invasion: Yes.

Surgical Margins: Vascular margin positive. Peripheral margin negative.

Necrosis: Yes.

Mitotic Rate: 2 per 50 high power field.

Grade: Low.

Lymph nodes status: Unknown.

Extra-adrenal extension: Yes (large vessel).

Stage: T4 NX

PROCEDURE: SPDX

1. Adrenal gland, resection: Low-grade adrenocortical carcinoma (15.5 cm and 1060 grams) with invasion of adjacent large vessels (stage T4). Please see TEMPLATE for details.

signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Source: NCI Genomic Data Commons file c798c414-25a6-421e-84c2-603f9d1a000b (TCGA-OR-A5K4.15A731FD-6B89-450D-A02B-A01DA759340A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).